Gene-level copy-number profile of tumor specimen TCGA-BS-A0TD-01A from TCGA case TCGA-BS-A0TD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Corpus uteri; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 65.6 years (23,950 days).
Specimen TCGA-BS-A0TD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.86430c4d-95c8-4346-8ed5-8d10b68113aa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BS-A0TD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6cd8b6a0-b446-4494-b398-035b3a25320b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 59,788; copy number 3: 23; copy number 5: 7; copy number 6: 1; copy number 7: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BS-A0TD-01A-11D-A102-01): tumor purity 0.61, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:89,900,664–89,990,883, 1 gene, copy number 7 (within-gene range 2–7): AC113167.1.
- chr5:155,491,336–155,493,598, 1 gene, copy number 6: AC008725.1.
- chr8:43,539,137–43,674,591, 5 genes, copy number 5: AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr11:21,383,801–21,383,909, 1 gene, copy number 5: RNA5SP337.
- chr11:54,724,847–54,725,816, 1 gene, copy number 5: OR4A6P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
